Somatic mutation profile of tumor specimen TCGA-D5-6530-01A (aliquot TCGA-D5-6530-01A-11D-1719-10) from TCGA case TCGA-D5-6530, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 53.6 years (19,591 days).
Specimen TCGA-D5-6530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd747b02-4ae2-4510-9991-e613e1d85ad4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6530-10A (Blood Derived Normal), aliquot TCGA-D5-6530-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6bbd768-5a05-483a-96e5-d6726dd3ce2c

The open-access MAF lists 1,306 somatic variants for this specimen: 979 protein-altering or splice-affecting, 301 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 618, Silent 301, Frame Shift Del 233, Frame Shift Ins 58, Nonsense Mutation 40, Intron 14, Splice Site 13, In Frame Del 11, RNA 5, 3'UTR 4, Splice Region 4, 3'Flank 2.

Variants (750 of 1,306; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5318C>T p.A1773V | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs760549861, CM087708, CM1210213, COSV64670966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 25/112 reads (22%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 258/702 reads (37%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 130/468 reads (28%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1B | c.6343C>T p.R2115* | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | catalogued as rs1554238072, CM1311939, COSV51664922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 294/791 reads (37%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5351del p.N1784Tfs*7 | Frame Shift Del (DEL) | VAF 64/200 reads (32%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CACNA1A | c.3544del p.L1182Sfs*8 | Frame Shift Del (DEL) | VAF 39/299 reads (13%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 282/402 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 202/645 reads (31%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.5563dup p.I1855Nfs*6 | Frame Shift Ins (INS) | VAF 184/584 reads (32%) | catalogued as rs752925056; ClinVar: pathogenic; called by mutect2, varscan2
- ESCO2 | c.1111dup p.T371Nfs*32 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | catalogued as rs80359859; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- KMT2B | c.7759C>T p.R2587* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as rs1555734923, COSV53073648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 153/208 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750206, CM093753, CM970953, CM990854, COSV51614574, COSV51617724; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 112/564 reads (20%) | catalogued as rs1064795023, COSV55546717; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 92/325 reads (28%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 58/252 reads (23%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RS1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 116/163 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs61752159, CM981753, COSV101183688; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 49/209 reads (23%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 93/342 reads (27%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- AACS | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.23); catalogued as rs753935697, COSV55537024; called by muse, mutect2, varscan2
- ABCA1 | c.1775del p.G592Afs*17 | Frame Shift Del (DEL) | VAF 108/307 reads (35%) | catalogued as rs766144819; called by mutect2, pindel, varscan2
- ABCA13 | c.12857G>A p.R4286Q | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs374724171; called by muse, mutect2, varscan2
- ABCA2 | c.6689C>T p.A2230V (on ENST00000614293; = p.A2200V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99686780; called by muse, mutect2, varscan2
- ABCF2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs145078285; called by muse, mutect2, varscan2
- ABCG4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746516183, COSV100266676, COSV56644190; called by muse, mutect2, varscan2
- ABI3BP | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV99425184; called by muse, mutect2, varscan2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 60/164 reads (37%) | catalogued as rs750897785; called by mutect2, pindel, varscan2
- ABRA | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.123); catalogued as rs1301517822, COSV100357447; called by muse, mutect2, varscan2
- ABTB2 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54388668; called by muse, mutect2, varscan2
- ACAN | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1221062169, COSV100716932; called by muse, mutect2
- ACAN | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100716934; called by muse, mutect2, varscan2
- ACAP3 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs373378336; called by muse, mutect2, varscan2
- ACBD5 | c.1271G>A p.R424Q (on ENST00000375888 / NM_001352568.1; = p.R415Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/444 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as rs543720340, COSV101022460; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 481/2713 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACOT12 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1312509130, COSV56897719; called by muse, mutect2, varscan2
- ACTBL2 | c.85del p.R29Gfs*7 | Frame Shift Del (DEL) | VAF 67/224 reads (30%) | catalogued as COSV101379250; called by mutect2, pindel, varscan2
- ACTN1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs913554480, COSV51991205; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ADAM23 | c.1395-2A>G p.X465_splice | Splice Site (SNP) | VAF 93/270 reads (34%) | catalogued as COSV52219842; called by muse, mutect2, varscan2
- ADAM29 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 127/407 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs753780341, COSV63667689; called by muse, mutect2, varscan2
- ADAMTS13 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs281875288, CM090520, COSV100746924; ClinVar: not provided; called by muse, mutect2, varscan2
- ADAMTS14 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746772566, COSV64601989; called by muse, mutect2, varscan2
- ADAMTS17 | c.2069G>C p.G690A | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99170347, COSV99170393; called by muse, mutect2, varscan2
- ADAMTS2 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs984794583, COSV52390209; called by muse, mutect2, varscan2
- ADAMTS4 | c.1846dup p.Q616Pfs*48 | Frame Shift Ins (INS) | VAF 32/106 reads (30%) | catalogued as rs1477734246; called by mutect2, varscan2
- ADAMTS7 | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV66308091; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446883671, COSV58443387; called by muse, mutect2, varscan2
- ADGRE5 | c.1873G>A p.A625T (on ENST00000242786 / NM_078481.4; = p.A532T on NM_001784.5) | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99660086; called by muse, mutect2, varscan2
- ADNP2 | c.971dup p.A325Cfs*59 | Frame Shift Ins (INS) | VAF 48/164 reads (29%) | catalogued as rs772825390; called by mutect2, varscan2
- AFDN | c.4780A>G p.M1594V | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1242700418, COSV60048056; called by muse, varscan2
- AGAP6 | c.1190C>T p.T397M (on ENST00000374056 / NM_001365867.1; = p.T420M on NM_001077665.2) | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs782521552, COSV100929028; called by muse, mutect2, varscan2
- AGO3 | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99867936; called by muse, mutect2, varscan2
- AGRN | c.3003del p.G1002Afs*38 | Frame Shift Del (DEL) | VAF 264/397 reads (66%) | catalogued as rs763573703; called by mutect2, varscan2
- AHNAK | c.12580C>T p.P4194S | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV57231205; called by muse, mutect2
- AHNAK | c.11039T>C p.L3680S | Missense Mutation (SNP) | VAF 168/441 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57213480, COSV99945388; called by muse, mutect2, varscan2
- AKR1B1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs755184764, COSV99605126; called by muse, mutect2, varscan2
- ALDH16A1 | c.1581del p.Y528Mfs*99 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | catalogued as rs764766875; called by mutect2, varscan2
- ALK | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV66574839; called by muse, mutect2, varscan2
- ALS2CL | c.2794C>T p.H932Y | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100014704; called by muse, mutect2, varscan2
- ALS2CL | c.1214A>C p.K405T | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100014709; called by muse, mutect2, varscan2
- AMN | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs866956966, COSV54487139; called by muse, mutect2, varscan2
- AMPD3 | c.734G>A p.S245N (on ENST00000396553 / NM_001025389.2; = p.S254N on NM_000480.3) | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1258358377, COSV101158073; called by muse, mutect2, varscan2
- AMPH | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs147284975; called by muse, mutect2, varscan2
- ANAPC2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs749355329, COSV59245037; called by muse, mutect2, varscan2
- ANGPTL1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 170/478 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs570797031, COSV99327926; called by muse, mutect2, varscan2
- ANKMY1 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 160/503 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369197129, COSV99801171; called by muse, mutect2, varscan2
- ANKRD24 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 161/445 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs764767359, COSV53672428; called by muse, mutect2, varscan2
- ANKRD50 | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101538876; called by muse, mutect2, varscan2
- ANO8 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752432408, COSV50184567; called by muse, mutect2, varscan2
- ANXA7 | c.1451C>T p.A484V (on ENST00000372919 / NM_001320880.2; = p.A462V on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100873386; called by muse, varscan2
- AP2A2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs530153811, COSV100172430; called by muse, mutect2, varscan2
- AP5Z1 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.409); catalogued as rs765261590, COSV100803990, COSV62243261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 103/286 reads (36%) | catalogued as rs546686089; called by mutect2, varscan2
- APLP1 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as COSV99383494; called by muse, mutect2, varscan2
- AQP7 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99951611; called by muse, mutect2, varscan2
- ARHGAP20 | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99503017; called by muse, mutect2, varscan2
- ARHGAP5 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 219/628 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100564966; called by muse, mutect2, varscan2
- ARHGEF1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs782681785, COSV100528945; called by muse, mutect2
- ARHGEF40 | c.3236G>A p.R1079H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs201070551; called by muse, mutect2, varscan2
- ARID2 | c.2552del p.P851Hfs*4 | Frame Shift Del (DEL) | VAF 139/457 reads (30%) | catalogued as rs751704736; called by mutect2, pindel, varscan2
- ARMC4 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100536256; called by muse, mutect2, varscan2
- ARMT1 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV100939735; called by muse, mutect2, varscan2
- ARSK | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 107/198 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV101187499; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 58/222 reads (26%) | catalogued as rs773893016; called by mutect2, varscan2
- ASB5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.163); catalogued as rs371622915; called by muse, mutect2, varscan2
- ASCL3 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); catalogued as COSV100366815; called by muse, mutect2, varscan2
- ASCL4 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.07); catalogued as rs1176000494, COSV100661135; called by muse, mutect2, varscan2
- ASH1L | c.8171G>A p.R2724H (on ENST00000368346 / NM_001366177.2; = p.R2719H on NM_018489.3) | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs375304383, COSV100853555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.4124C>T p.A1375V | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV52470787; called by muse, mutect2, varscan2
- ATAD5 | c.4136T>C p.V1379A | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100429617; called by muse, mutect2, varscan2
- ATAD5 | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs994324226, COSV100429620; called by muse, mutect2, varscan2
- ATF7 | c.1076G>A p.R359H (on ENST00000548446 / NM_001366555.2; = p.R348H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129819, COSV60644725; called by muse, mutect2, varscan2
- ATM | c.7310A>G p.Y2437C | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1555122944, COSV53737967, COSV53747491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B4 | c.2497G>T p.G833* | Nonsense Mutation (SNP) | VAF 205/591 reads (35%) | catalogued as COSV100396998; called by muse, mutect2, varscan2
- ATP6V1E1 | c.562C>A p.R188S | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV53657009, COSV99494162; called by muse, mutect2
- ATP8A2 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99679787; called by muse, mutect2
- ATP8B1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs148715351; ClinVar: uncertain significance; called by muse, varscan2
- ATP9B | c.1831A>G p.T611A | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100302766; called by muse, mutect2, varscan2
- ATR | c.3402dup p.N1135* | Frame Shift Ins (INS) | VAF 303/884 reads (34%) | catalogued as rs1043355995; called by mutect2, varscan2
- ATRN | c.1406C>A p.P469H | Missense Mutation (SNP) | VAF 217/623 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370919111, COSV99496482; called by muse, mutect2, varscan2
- BANP | c.470G>A p.R157H (on ENST00000286122; = p.R126H on NM_017869.4) | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs773807056, COSV99620623; called by muse, varscan2
- BAX | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 115/295 reads (39%) | catalogued as COSV53169046; called by muse, mutect2, varscan2
- BBS9 | c.1966C>T p.R656W (on ENST00000242067 / NM_001348036.1; = p.R616W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762045410, COSV54193988; called by muse, mutect2, varscan2
- BCR | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs770962732, COSV100005910; called by muse, mutect2, varscan2
- BLK | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99376809; called by muse, mutect2, varscan2
- BMP4 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99816717; called by muse, mutect2, varscan2
- BNIP5 | c.1857G>C p.M619I | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101465210, COSV71325650; called by muse, mutect2, varscan2
- BPTF | c.7666C>T p.P2556S | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV100073916, COSV58833168; called by muse, mutect2, varscan2
- BSN | c.10343C>A p.A3448E | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99607120; called by muse, mutect2
- BTBD16 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747263313, COSV99584465; called by muse, mutect2, varscan2
- BTN2A1 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 123/357 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs781067055, COSV57004351; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 138/494 reads (28%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- C2orf69 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs755755680, COSV60666564; called by muse, mutect2, varscan2
- C3 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867467891, COSV55570995; called by muse, mutect2, varscan2
- CACNA2D1 | c.1262T>C p.I421T | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1417891305, COSV100665668; called by muse, mutect2, varscan2
- CACNB1 | c.417A>G p.K139= | Splice Region (SNP) | VAF 49/164 reads (30%) | catalogued as COSV100703287; called by muse, mutect2, varscan2
- CACNB4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 110/367 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV52396833; called by muse, mutect2, varscan2
- CACUL1 | c.1025+1G>A p.X342_splice | Splice Site (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100432403; called by muse, mutect2, varscan2
- CADM1 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 271/744 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as rs1235105339, COSV59017162; called by muse, mutect2, varscan2
- CALR3 | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 158/464 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99522037; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 48/124 reads (39%) | catalogued as rs745547658; called by mutect2, varscan2
- CARMIL1 | c.1067A>G p.H356R | Missense Mutation (SNP) | VAF 224/661 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100276739; called by muse, mutect2, varscan2
- CATSPERD | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 354/953 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770610933, COSV101062336, COSV67534579; called by muse, varscan2
- CCDC124 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 113/285 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs762625853, COSV101506479; called by muse, mutect2, varscan2
- CCDC180 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs750998788, COSV100826533; called by muse, mutect2, varscan2
- CCDC74B | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.163); catalogued as COSV100134138; called by muse, mutect2, varscan2
- CCDC92 | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV99435159; called by muse, mutect2, varscan2
- CCL28 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs775586405, COSV63149299; called by muse, mutect2, varscan2
- CD101 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV99869060; called by muse, mutect2, varscan2
- CD7 | c.625_626del p.C209Lfs*5 | Frame Shift Del (DEL) | VAF 39/197 reads (20%) | catalogued as rs1567837872; called by pindel, varscan2
- CD93 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1424143182, COSV99848852; called by muse, mutect2, varscan2
- CD96 | c.1513G>A p.V505I (on ENST00000283285 / NM_198196.3; = p.V489I on NM_005816.5) | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372441714, COSV51918649; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 123/394 reads (31%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC20B | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs368819650; called by muse, mutect2, varscan2
- CDH16 | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100233622; called by muse, mutect2, varscan2
- CDH5 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.21); catalogued as COSV100438980; called by muse, mutect2, varscan2
- CDHR5 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755331585, COSV62764032; called by muse, mutect2, varscan2
- CDR2 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99193477; called by muse, mutect2, varscan2
- CDRT4 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 159/453 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100381490; called by muse, mutect2, varscan2
- CELA3B | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs770209220, COSV100448579; called by muse, mutect2, varscan2
- CELSR1 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439286436, COSV99416621; called by muse, mutect2, varscan2
- CENPF | c.8647A>T p.T2883S | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV100871472; called by muse, mutect2, varscan2
- CEP192 | c.4574G>A p.R1525Q | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs143777613; called by muse, varscan2
- CEP63 | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100132523; called by muse, mutect2, varscan2
- CEP85 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99431691; called by muse, mutect2, varscan2
- CETP | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs200956328, COSV99569828; called by muse, mutect2, varscan2
- CFAP44 | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 207/671 reads (31%) | catalogued as rs752337230, COSV55613033; called by muse, mutect2, varscan2
- CFAP54 | c.8235A>T p.E2745D | Missense Mutation (SNP) | VAF 141/436 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100732906; called by muse, mutect2, varscan2
- CHD5 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756337392, COSV99312326; called by muse, mutect2, varscan2
- CHD7 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs776871277, COSV101417966; called by muse, mutect2, varscan2
- CHRD | c.1573T>C p.C525R | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV52609547; called by muse, mutect2, varscan2
- CHRD | c.1693C>A p.L565M | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52609556; called by muse, mutect2, varscan2
- CHRFAM7A | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 237/815 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371215984; called by muse, mutect2, varscan2
- CHRNA5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs200127699, COSV55138194, COSV55139165; called by muse, mutect2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 105/334 reads (31%) | catalogued as COSV50671496; called by mutect2, varscan2
- CIR1 | c.707del p.K236Rfs*104 | Frame Shift Del (DEL) | VAF 54/159 reads (34%) | catalogued as rs1194821230; called by mutect2, varscan2
- CLCA4 | c.544del p.I182Sfs*56 | Frame Shift Del (DEL) | VAF 50/129 reads (39%) | catalogued as rs760255767; called by mutect2, varscan2
- CLEC9A | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63350877; called by muse, varscan2
- CNOT4 | c.1987C>T p.Q663* (on ENST00000541284 / NM_001190850.1; = p.Q589* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 100/314 reads (32%) | catalogued as COSV64158476; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 64/213 reads (30%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN5 | c.2693A>G p.H898R | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.478); catalogued as COSV99672400; called by muse, mutect2, varscan2
- CNTNAP5 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 139/420 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV70488253; called by muse, mutect2, varscan2
- COL6A6 | c.92del p.L31Wfs*16 | Frame Shift Del (DEL) | VAF 238/786 reads (30%) | catalogued as COSV100650165; called by mutect2, pindel, varscan2
- COL8A1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs745489693, COSV53737019, COSV99658308; called by muse, mutect2, varscan2
- CORO1A | c.549C>G p.D183E | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1337369430, COSV99531793; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 68/200 reads (34%) | catalogued as rs750161916; called by mutect2, varscan2
- CPED1 | c.1686A>G p.I562M | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100119895; called by muse, varscan2
- CRACDL | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs772608832, COSV67408898; called by muse, mutect2, varscan2
- CREB3L1 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 275/754 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99914808; called by muse, mutect2, varscan2
- CRISPLD1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51543751; called by muse, mutect2, varscan2
- CRYBG2 | c.4619del p.G1540Dfs*12 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | catalogued as rs1557701360; called by mutect2, varscan2
- CRYBG3 | c.6568G>A p.V2190I | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs768639623, COSV51713764, COSV99476741; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 47/152 reads (31%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTU2 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100371905, COSV56381459; called by muse, mutect2, varscan2
- CUBN | c.1015+1G>A p.X339_splice | Splice Site (SNP) | VAF 42/123 reads (34%) | catalogued as rs192997971, COSV100912012, COSV64725295; called by muse, mutect2, varscan2
- CUL9 | c.2269C>A p.L757M | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV99334678; called by muse, mutect2, varscan2
- CUL9 | c.3980G>A p.R1327Q | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs751503492, COSV99334681; called by muse, mutect2, varscan2
- CWF19L1 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 61/168 reads (36%) | catalogued as COSV100821441; called by muse, varscan2
- CYC1 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100010196, COSV100010427; called by muse, mutect2
- CYLD | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100282124; called by muse, mutect2, varscan2
- DBNDD2 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772958543, COSV100619505; called by muse, mutect2, varscan2
- DCHS1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs147257039; called by muse, mutect2, varscan2
- DDX46 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 225/637 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1202348931, COSV62799152; called by muse, varscan2
- DDX47 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs762415203, COSV100774472; called by muse, mutect2, varscan2
- DENND1C | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV67375238; called by muse, varscan2
- DENND4B | c.304dup p.L102Pfs*3 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | catalogued as rs747842790; called by mutect2, varscan2
- DHPS | c.758del p.P253Rfs*11 | Frame Shift Del (DEL) | VAF 83/278 reads (30%) | catalogued as COSV99269620; called by mutect2, pindel, varscan2
- DHX40 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 254/760 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1331102900, COSV99232680; called by muse, mutect2, varscan2
- DISP2 | c.3028C>A p.L1010I | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99139669; called by muse, mutect2, varscan2
- DMXL1 | c.4856G>A p.R1619H | Missense Mutation (SNP) | VAF 231/600 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150395383, COSV60709485; called by muse, mutect2, varscan2
- DNAAF1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574238677, COSV57577092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.8736C>A p.D2912E | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as COSV101324565, COSV70236248; called by muse, mutect2, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 76/281 reads (27%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAH5 | c.5927del p.G1976Efs*78 | Frame Shift Del (DEL) | VAF 123/378 reads (33%) | catalogued as rs1233412023, COSV54222791; called by mutect2, pindel, varscan2
- DNAJB2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 23/501 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1415279774, COSV100338815; ClinVar: uncertain significance; called by muse, mutect2
- DNASE1 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs772877991, COSV55913040, COSV55913322; called by muse, mutect2, varscan2
- DOCK1 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV54729863, COSV54743083; called by muse, mutect2, varscan2
- DOCK2 | c.2109T>A p.H703Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99910055; called by muse, mutect2, varscan2
- DPF1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 134/392 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1242183452, COSV100831408; called by muse, mutect2, varscan2
- DPP10 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs566062096, COSV59697055; called by muse, mutect2, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 224/615 reads (36%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2, varscan2
- DYSF | c.5076G>A p.W1692* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99243985; called by muse, mutect2, varscan2
- ECE1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918103; called by muse, mutect2, varscan2
- EDC4 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772976256, COSV59303116; called by muse, mutect2, varscan2
- EDEM2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs368321216; called by muse, mutect2
- EFCAB13 | c.2701A>G p.K901E | Missense Mutation (SNP) | VAF 207/564 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100516314; called by muse, mutect2, varscan2
- EHMT2 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV64996686; called by muse, mutect2, varscan2
- EIF3A | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100974476; called by muse, mutect2, varscan2
- EIF4A3 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 155/464 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483932; called by muse, mutect2, varscan2
- EIF4G3 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777228085, COSV51679767, COSV51692966; called by muse, mutect2, varscan2
- ELMO3 | c.2251C>T p.R751W (on ENST00000652269; = p.R698W on NM_024712.5) | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs750093350, COSV58528884; called by muse, mutect2, varscan2
- EML3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV53883121; called by muse, mutect2, varscan2
- ENPP5 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.089); catalogued as rs1227984035, COSV57909205; called by muse, mutect2, varscan2
- EPG5 | c.3505A>G p.M1169V | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.406); catalogued as rs747668301, COSV99956399; called by muse, mutect2, varscan2
- EPHB1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1415689583, COSV67659496; called by muse, mutect2, varscan2
- ERBB2 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs747888253, CM142385, COSV54067403; called by muse, mutect2, varscan2
- ERBB4 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs762478821, COSV99615669; called by muse, mutect2, varscan2
- ERG | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 160/529 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV99901094; called by muse, mutect2, varscan2
- ERI3 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as COSV100261511; called by muse, mutect2, varscan2
- ERICH6 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 90/289 reads (31%) | catalogued as COSV99901311; called by muse, mutect2, varscan2
- ERLIN2 | c.*6del | Frame Shift Del (DEL) | VAF 48/173 reads (28%) | catalogued as COSV99379658; called by mutect2, pindel, varscan2
- ERRFI1 | c.406T>C p.S136P | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV101087947; called by muse, mutect2, varscan2
- EVC2 | c.2158A>G p.T720A | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100184925; called by muse, mutect2, varscan2
- EXOC7 | c.1148C>T p.A383V (on ENST00000335146 / NM_001145297.4; = p.A301V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100134804; called by muse, mutect2, varscan2
- EXTL1 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100958472; called by muse, mutect2, varscan2
- FAAH2 | c.977T>G p.L326R | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100887144; called by muse, mutect2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM136A | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs745624131, COSV99231863; called by muse, mutect2, varscan2
- FAM13A | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 25/735 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99982789; called by muse, mutect2
- FAM161B | c.1688G>A p.R563H (on ENST00000651776; = p.R500H on NM_152445.3) | Missense Mutation (SNP) | VAF 197/759 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754779063, COSV54102988; called by muse, mutect2, varscan2
- FAM3B | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63613649; called by muse, mutect2, varscan2
- FAM47C | c.2013del p.E672Rfs*153 | Frame Shift Del (DEL) | VAF 155/312 reads (50%) | catalogued as rs781887428; called by mutect2, pindel, varscan2
- FAM83G | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100524756; called by muse, mutect2, varscan2
- FAN1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1315381732, COSV100755791; called by muse, mutect2, varscan2
- FANCA | c.4096C>T p.Q1366* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as rs1336834251, COSV99234517, COSV99234955; called by muse, mutect2, varscan2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 36/217 reads (17%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel, varscan2
- FANCI | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 160/383 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs779515039, COSV55529504; called by muse, mutect2, varscan2
- FAT4 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs751046172, COSV101271808; called by muse, mutect2, varscan2
- FAT4 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs1560752711, COSV101271809; called by muse, mutect2, varscan2
- FAT4 | c.4952T>C p.I1651T | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV101271810; called by muse, mutect2, varscan2
- FAT4 | c.13686C>A p.D4562E | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100627160; called by muse, mutect2, varscan2
- FBLIM1 | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1454344203, COSV60030408; called by muse, mutect2, varscan2
- FBN3 | c.4342G>A p.E1448K | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144956618; called by muse, mutect2, varscan2
- FCGBP | c.10546G>A p.A3516T | Missense Mutation (SNP) | VAF 138/360 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs1424589357; called by muse, mutect2, varscan2
- FCRL3 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 155/423 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs201961888, COSV63840559; called by muse, mutect2, varscan2
- FEM1B | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60987747, COSV60988921; called by muse, mutect2, varscan2
- FGF2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1424847946, COSV99144557; called by muse, mutect2, varscan2
- FGFR2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 169/484 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.285); catalogued as rs776868501, COSV100335278; called by muse, mutect2, varscan2
- FHL3 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as rs1163040519, COSV100885045; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 107/307 reads (35%) | catalogued as rs774060142; called by mutect2, varscan2
- FKBP6 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV52721069; called by muse, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 99/329 reads (30%) | catalogued as rs752076602; called by mutect2, varscan2
- FLG2 | c.4481C>T p.T1494I | Missense Mutation (SNP) | VAF 302/888 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV101165577; called by muse, mutect2, varscan2
- FNDC1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775569158, COSV51939676; called by muse, mutect2, varscan2
- FNDC1 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99794783; called by muse, mutect2, varscan2
- FOXD4L5 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 352/2160 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV101073005; called by muse, mutect2, varscan2
- FOXK1 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194538; called by muse, mutect2, varscan2
- FRY | c.4543C>T p.P1515S | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968665; called by muse, mutect2, varscan2
- FUT5 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.625); catalogued as rs755351741, COSV99398489, COSV99398879; called by muse, mutect2, varscan2
- FUT8 | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1423086084, COSV100650992; called by muse, mutect2, varscan2
- GAL3ST4 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 67/163 reads (41%) | catalogued as rs570514466, COSV100385672, COSV57586143; called by muse, mutect2, varscan2
- GAPVD1 | c.2852C>T p.P951L (on ENST00000394104; = p.P978L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs752197679, COSV99782584; called by muse, mutect2, varscan2
- GARS1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013921090, COSV66827762; called by muse, mutect2, varscan2
- GATAD2B | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 206/621 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764367916, COSV100897770; called by muse, mutect2, varscan2
- GBP6 | c.1153-2A>G p.X385_splice | Splice Site (SNP) | VAF 56/156 reads (36%) | catalogued as rs750184642, COSV100969452; called by muse, varscan2
- GCH1 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM135179, CM994199, COSV54304420; called by muse, mutect2, varscan2
- GCM2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101069419; called by muse, mutect2, varscan2
- GCN1 | c.5380C>T p.R1794C | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459990599, COSV56105039; called by muse, mutect2, varscan2
- GDPD5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1405132857, COSV61126659; called by muse, mutect2, varscan2
- GGA3 | c.863G>A p.R288Q (on ENST00000537686 / NM_138619.4; = p.R255Q on NM_014001.5) | Missense Mutation (SNP) | VAF 138/442 reads (31%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.606); catalogued as rs1253818685, COSV99821865; called by muse, mutect2, varscan2
- GIMAP7 | c.788dup p.N263Kfs*7 | Frame Shift Ins (INS) | VAF 23/75 reads (31%) | catalogued as rs1175406602; called by mutect2, pindel, varscan2
- GLB1L3 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs760273413, COSV68392669; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 71/267 reads (27%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLP1R | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64715275; called by muse, mutect2, varscan2
- GLT8D1 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 156/444 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.891); catalogued as COSV99803486; called by muse, mutect2, varscan2
- GMEB1 | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV99602926; called by muse, mutect2, varscan2
- GMEB2 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV99823403; called by muse, mutect2, varscan2
- GNA14 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 35/765 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100502488; called by muse, mutect2
- GON4L | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV55195860; called by muse, mutect2, varscan2
- GPR158 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747936646, COSV66270630; called by muse, mutect2, varscan2
- GPR32 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 127/364 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs879062227, COSV54514708; called by muse, mutect2, varscan2
- GPS1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as COSV100135808; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 44/126 reads (35%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2B | c.3838A>G p.K1280E | Missense Mutation (SNP) | VAF 106/421 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.229); catalogued as rs772502958, COSV101662893; called by muse, mutect2, varscan2
- GRM7 | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 116/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100735510, COSV63142675; called by muse, mutect2, varscan2
- GRM8 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs553468202, COSV58817945; called by muse, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 106/368 reads (29%) | catalogued as COSV58842099; called by pindel, varscan2
- GSTA3 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 274/857 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99274398; called by muse, mutect2, varscan2
- GSTZ1 | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV99374336; called by muse, mutect2, varscan2
- GTF3C2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 121/344 reads (35%) | catalogued as rs768563502, COSV99272103; called by muse, mutect2, varscan2
- H3C8 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV100009983; called by muse, varscan2
- HDAC11 | c.375del p.K126Sfs*154 | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | catalogued as rs1200071189; called by mutect2, pindel, varscan2
- HDAC9 | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV101286815, COSV67776950; called by muse, mutect2, varscan2
- HDLBP | c.3802C>T p.R1268* | Nonsense Mutation (SNP) | VAF 62/377 reads (16%) | catalogued as rs1229026680, COSV99237209; called by muse, mutect2, varscan2
- HECTD4 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759295110, COSV66394426; called by muse, mutect2, varscan2
- HELZ2 | c.5870C>T p.A1957V (on ENST00000467148 / NM_001037335.2; = p.A1388V on NM_033405.3) | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs772680501, COSV101427511; called by muse, mutect2, varscan2
- HERC1 | c.8798A>G p.D2933G | Missense Mutation (SNP) | VAF 146/488 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.1); catalogued as COSV101496300; called by muse, mutect2, varscan2
- HERC1 | c.6202A>G p.T2068A | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV101496301; called by muse, mutect2, varscan2
- HERPUD2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407087419, COSV100257782; called by muse, mutect2, varscan2
- HESX1 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 136/398 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1412077914, COSV99907646; called by muse, mutect2, varscan2
- HEY1 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.073); catalogued as rs1479952582, COSV100559149; called by muse, mutect2, varscan2
- HID1 | c.1346T>C p.M449T | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1316686185, COSV100585927; called by muse, mutect2, varscan2
- HIPK1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 148/397 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61247078; called by muse, mutect2, varscan2
- HIRA | c.1744C>A p.L582M | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV54276522; called by muse, mutect2, varscan2
- HK2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs567201785, COSV51873869; called by muse, mutect2, varscan2
- HNRNPH1 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 243/683 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV61486971; called by muse, mutect2, varscan2
- HORMAD1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100463791; called by muse, mutect2, varscan2
- HP | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 175/523 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs371304177; called by muse, mutect2, varscan2
- HPS1 | c.1907T>A p.V636E | Missense Mutation (SNP) | VAF 116/326 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV100282293; called by muse, mutect2, varscan2
- HRNR | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs763238586, COSV64255150; called by muse, mutect2, varscan2
- HSD11B1L | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as COSV100028409; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 97/321 reads (30%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- HSPG2 | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs373895855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUWE1 | c.6949G>A p.D2317N | Missense Mutation (SNP) | VAF 128/175 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99470484; called by muse, mutect2, varscan2
- HYDIN | c.5626C>T p.R1876W | Missense Mutation (SNP) | VAF 85/535 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189741059, COSV59269613; called by muse, mutect2, varscan2
- IARS1 | c.608A>C p.D203A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100986770; called by muse, mutect2, varscan2
- IFI44 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769794841, COSV100877259; called by muse, mutect2, varscan2
- IGSF10 | c.4925G>T p.R1642M | Missense Mutation (SNP) | VAF 265/818 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV56784255, COSV99176578; called by muse, mutect2, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as COSV63641012; called by mutect2, varscan2
- IHH | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99838579; called by muse, mutect2, varscan2
- IHO1 | c.1314del p.D440Tfs*18 | Frame Shift Del (DEL) | VAF 91/296 reads (31%) | catalogued as COSV56511435; called by mutect2, pindel, varscan2
- IL1RL2 | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 161/505 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV99960190; called by muse, mutect2, varscan2
- INCENP | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV53917340, COSV53921746; called by muse, mutect2, varscan2
- INO80E | c.531del p.D178Tfs*8 | Frame Shift Del (DEL) | VAF 114/432 reads (26%) | catalogued as rs1339809802; called by pindel, varscan2
- INTS10 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs754588177, COSV67604519; called by muse, mutect2, varscan2
- INTU | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1439201650, COSV100080386; called by muse, mutect2, varscan2
- IP6K3 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs766496518, COSV99539563; called by muse, mutect2, varscan2
- IQCE | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs113031380, COSV100383158, COSV58077142; called by muse, mutect2, varscan2
- ITGAL | c.2474del p.P825Rfs*11 | Frame Shift Del (DEL) | VAF 82/275 reads (30%) | catalogued as COSV100776292; called by mutect2, pindel, varscan2
- ITGB2 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100185559; called by muse, mutect2, varscan2
- ITGB7 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs755135151, COSV99913892; called by muse, mutect2, varscan2
- ITIH2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs375764473; called by muse, mutect2, varscan2
- ITSN1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 154/448 reads (34%) | catalogued as COSV66085823; called by muse, mutect2, varscan2
- JADE2 | c.1669C>A p.R557S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99252698; called by muse, mutect2, varscan2
- JARID2 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202079041, COSV100521219; called by muse, mutect2, varscan2
- JRK | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as rs1405928839, COSV101401026; called by muse, mutect2, varscan2
- KAT5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as COSV100383801, COSV57729586; called by muse, mutect2, varscan2
- KBTBD12 | c.1835del p.P612Rfs*78 | Frame Shift Del (DEL) | VAF 93/358 reads (26%) | catalogued as rs1187501286, COSV100675484; called by mutect2, pindel, varscan2
- KCNA1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 229/600 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101230097; called by muse, mutect2, varscan2
- KCNAB3 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.036); catalogued as rs1486751711, COSV100375913; called by muse, mutect2, varscan2
- KCNB1 | c.2206dup p.R736Pfs*4 | Frame Shift Ins (INS) | VAF 64/194 reads (33%) | catalogued as rs759902465; called by mutect2, varscan2
- KCNH6 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs752536722, COSV59002852; called by muse, mutect2, varscan2
- KCNK18 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 16/458 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100571968; called by muse, mutect2
- KCNQ4 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282247264, COSV100714268; called by muse, mutect2, varscan2
- KDM8 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99619183; called by muse, mutect2, varscan2
- KIAA0753 | c.2411C>A p.P804H | Missense Mutation (SNP) | VAF 164/504 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100810521; called by muse, mutect2, varscan2
- KIAA1549 | c.3622C>T p.R1208W | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649659; called by muse, mutect2, varscan2
- KIAA1755 | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs140768307; called by muse, mutect2, varscan2
- KIF11 | c.3029C>A p.P1010Q | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99585616; called by muse, mutect2
- KIF1A | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100239741; called by muse, mutect2, varscan2
- KIF26A | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 247/712 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs764349709, COSV100180696, COSV59467434; called by muse, mutect2, varscan2
- KIF26B | c.4267T>A p.S1423T | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV63644777; called by muse, mutect2, varscan2
- KIF2C | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1029002934, COSV64766151; called by muse, mutect2, varscan2
- KIFC1 | c.699dup p.Q234Tfs*52 | Frame Shift Ins (INS) | VAF 33/90 reads (37%) | catalogued as rs1562835347; called by mutect2, varscan2
- KIFC3 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs782252277, COSV101109075; called by muse, mutect2, varscan2
- KLHL1 | c.1458G>A p.W486* | Nonsense Mutation (SNP) | VAF 165/486 reads (34%) | catalogued as COSV100916935; called by muse, mutect2, varscan2
- KLHL10 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1302156953, COSV53173028; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 41/149 reads (28%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 58/250 reads (23%) | catalogued as rs960845807, COSV54929560; called by pindel, varscan2
- KRT18 | c.241_243del p.K81del | In Frame Del (DEL) | VAF 29/81 reads (36%) | catalogued as rs1171454796; called by mutect2, varscan2
- KRT25 | c.66A>T p.R22S | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100379790; called by muse, mutect2, varscan2
- KRT38 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as rs780324275, COSV55846527; called by muse, mutect2, varscan2
- KRT5 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 149/456 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as rs755300932, COSV99357764; called by muse, mutect2, varscan2
- KRT79 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100398271; called by muse, mutect2, varscan2
- KRT84 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs200397824, COSV57770646; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 52/231 reads (23%) | catalogued as rs770565486; called by pindel, varscan2*
- LAMA2 | c.3372del p.K1124Nfs*15 | Frame Shift Del (DEL) | VAF 92/316 reads (29%) | catalogued as rs1361925574, COSV70347760; called by mutect2, pindel, varscan2
- LAMB2 | c.4274del p.G1425Vfs*27 | Frame Shift Del (DEL) | VAF 62/178 reads (35%) | catalogued as COSV59731620; called by mutect2, varscan2
- LAMB2 | c.3686G>A p.S1229N | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV59734959; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 211/365 reads (58%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGALS14 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 192/546 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182437481, COSV100648398; called by muse, mutect2, varscan2
- LGALS9 | c.812G>A p.R271H (on ENST00000395473 / NM_009587.3; = p.R239H on NM_002308.4) | Missense Mutation (SNP) | VAF 230/695 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs147965169; called by muse, mutect2, varscan2
- LILRA4 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 188/490 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs181991337, COSV52493325; called by muse, mutect2, varscan2
- LMNA | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs397517913, COSV100738465; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1 | c.8386G>A p.G2796S | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs148421667; called by muse, mutect2, varscan2
- LRP2 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs950601446, COSV99786338; called by muse, mutect2, varscan2
- LRP5 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1410398990, COSV53716424; called by muse, mutect2, varscan2
- LRRC15 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100752586; called by muse, mutect2
- LRRC37A3 | c.3912del p.K1304Nfs*11 | Frame Shift Del (DEL) | VAF 208/695 reads (30%) | catalogued as rs1261486978; called by mutect2, pindel, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRC42 | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV59961141; called by muse, mutect2, varscan2
- LRRC49 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs767081330, COSV99536791; called by muse, mutect2, varscan2
- LRRC7 | c.3245C>T p.A1082V (on ENST00000651989 / NM_001370785.2; = p.A1049V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV99224222; called by muse, mutect2, varscan2
- LRRFIP2 | c.567C>A p.A189= | Splice Region (SNP) | VAF 124/383 reads (32%) | catalogued as COSV100368114; called by muse, mutect2, varscan2
- LRRK1 | c.3914G>A p.R1305Q | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99437310, COSV99440520; called by muse, mutect2, varscan2
- LTBR | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99965162; called by muse, mutect2, varscan2
- LTBR | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57439201; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 38/272 reads (14%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- MACF1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 67/186 reads (36%) | catalogued as rs186743740, COSV58374353; called by muse, mutect2, varscan2
- MACF1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 105/264 reads (40%) | catalogued as COSV100482143; called by muse, mutect2, varscan2
- MACF1 | c.5608G>A p.A1870T | Missense Mutation (SNP) | VAF 101/300 reads (34%) | catalogued as rs1404224843, COSV99240914; called by muse, mutect2, varscan2
- MACROH2A2 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952297; called by muse, mutect2, varscan2
- MAEA | c.1010G>A p.R337H (on ENST00000303400 / NM_001017405.3; = p.R296H on NM_005882.5) | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1316213320, COSV53262363; called by muse, mutect2, varscan2
- MAGI2 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100832466; called by muse, mutect2, varscan2
- MAP3K10 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 137/359 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1462440579, COSV99453916; called by muse, mutect2, varscan2
- MAP3K20 | c.2277G>T p.E759D | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100919376; called by muse, varscan2
- MAP3K21 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766210520, COSV100786114, COSV64041629; called by muse, mutect2, varscan2
- MAP7D1 | c.107dup p.P37Tfs*24 | Frame Shift Ins (INS) | VAF 119/372 reads (32%) | catalogued as rs749986670; called by mutect2, varscan2
- MAPRE2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55819870; called by muse, mutect2, varscan2
- MARF1 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs372638277, COSV60025386; called by muse, mutect2, varscan2
- MARK2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100158017; called by muse, mutect2, varscan2
- MARK3 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1415275487, COSV53511076; called by muse, mutect2, varscan2
- MASP1 | c.1303G>T p.V435L | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV99396723; called by muse, mutect2, varscan2
- MAST3 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 115/364 reads (32%) | catalogued as COSV53224290; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs762648935; called by mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 84/245 reads (34%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MBTPS1 | c.2896C>T p.R966* | Nonsense Mutation (SNP) | VAF 62/207 reads (30%) | catalogued as COSV100597324; called by muse, mutect2, varscan2
- MCF2L | c.718A>G p.M240V (on ENST00000375608; = p.M208V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65050357; called by muse, mutect2, varscan2
- MCRIP2 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99552592; called by muse, mutect2, varscan2
- MCRS1 | c.235del p.V79Wfs*41 | Frame Shift Del (DEL) | VAF 138/409 reads (34%) | catalogued as rs1313826230; called by mutect2, pindel, varscan2
- MDC1 | c.3909del p.K1304Sfs*57 | Frame Shift Del (DEL) | VAF 194/629 reads (31%) | catalogued as COSV64526663; called by mutect2, pindel, varscan2
- MED25 | c.602dup p.A202Gfs*197 | Frame Shift Ins (INS) | VAF 82/250 reads (33%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MET | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV59256988; called by muse, mutect2, varscan2
- METTL4 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs754884251, COSV60605666; called by muse, mutect2, varscan2
- MFGE8 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772280903, COSV51556018; called by muse, mutect2, varscan2
- MGAT4A | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 70/183 reads (38%) | catalogued as rs141026005; called by muse, mutect2, varscan2
- MGAT4C | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100152586, COSV59835310; called by muse, mutect2, varscan2
- MIA2 | c.2162del p.P721Hfs*30 | Frame Shift Del (DEL) | VAF 100/533 reads (19%) | catalogued as rs780386330; called by mutect2, pindel, varscan2
- MIA3 | c.2739G>T p.E913D | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100719258; called by muse, mutect2, varscan2
- MIB1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as rs376597435; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 45/130 reads (35%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINDY1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749897207, COSV56497289; called by muse, mutect2, varscan2
- MINPP1 | c.792dup p.V265Sfs*11 | Frame Shift Ins (INS) | VAF 138/416 reads (33%) | catalogued as rs1487068341; called by mutect2, varscan2
- MKRN3 | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100090647; called by muse, mutect2, varscan2
- MLLT6 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1295487709; called by muse, mutect2, varscan2
- MOGAT2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554620597, COSV99549348; called by muse, mutect2, varscan2
- MPP1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 196/290 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs201827720, COSV65729829; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 96/319 reads (30%) | catalogued as rs1558718327, COSV62567684; called by mutect2, pindel, varscan2
- MRPS30 | c.972del p.F324Lfs*37 | Frame Shift Del (DEL) | VAF 83/274 reads (30%) | catalogued as rs764773638; called by mutect2, pindel, varscan2
- MRPS31 | c.739del p.R247Gfs*15 | Frame Shift Del (DEL) | VAF 58/180 reads (32%) | catalogued as COSV100062133; called by pindel, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 42/133 reads (32%) | catalogued as rs34028511; called by mutect2, varscan2
- MSI2 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 104/279 reads (37%) | catalogued as COSV52361861; called by muse, mutect2, varscan2
- MTDH | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV100292312; called by muse, mutect2, varscan2
- MTERF1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 75/204 reads (37%) | catalogued as rs377191303, COSV61098490; called by muse, mutect2, varscan2
- MTHFSD | c.980G>A p.R327Q (on ENST00000360900 / NM_001159377.2; = p.R326Q on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as rs761252808, COSV59803874; called by muse, mutect2, varscan2
- MUC5AC | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); catalogued as COSV100650514; called by muse, mutect2, varscan2
- MUC5B | c.14116del p.T4706Pfs*4 | Frame Shift Del (DEL) | VAF 346/1174 reads (29%) | catalogued as COSV71592533; called by mutect2, pindel, varscan2
- MXRA5 | c.7222G>T p.A2408S | Missense Mutation (SNP) | VAF 125/185 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54235179, COSV54244508; called by muse, mutect2, varscan2
- MYCBP2 | c.3307C>T p.R1103* (on ENST00000357337; = p.R1141* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 58/169 reads (34%) | catalogued as COSV62026566; called by muse, mutect2, varscan2
- MYH7B | c.5495_5497del p.K1832del | In Frame Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs768844932; called by pindel, varscan2
- MYO18B | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754694367, COSV59132288; called by muse, mutect2, varscan2
- MYO1H | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100183059; called by muse, mutect2, varscan2
- MYO5A | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 169/435 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs778992454, COSV100697262; called by muse, mutect2, varscan2
- MYPN | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 195/534 reads (37%) | catalogued as COSV100589484; called by muse, mutect2, varscan2
- N4BP1 | c.1915T>G p.C639G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV52211604; called by muse, mutect2, varscan2
- NAALADL2 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV101458162, COSV70296003; called by muse, mutect2, varscan2
- NAALADL2 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV101495160; called by muse, mutect2, varscan2
- NAGPA | c.942T>A p.C314* | Nonsense Mutation (SNP) | VAF 113/323 reads (35%) | catalogued as COSV100392795; called by muse, mutect2, varscan2
- NALCN | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99212807; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NBAS | c.4487A>G p.Q1496R | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99866888; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 71/266 reads (27%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCOA6 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs751187935, COSV62860928; called by muse, mutect2, varscan2
- NCOR1 | c.2056A>T p.T686S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV99063170, COSV99246880; called by muse, mutect2, varscan2
- NEB | c.10370A>G p.D3457G | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1442287583, COSV99414334; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 155/492 reads (32%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NEIL1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV100748487; called by muse, mutect2, varscan2
- NEK9 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.761); catalogued as COSV99463437; called by muse, mutect2, varscan2
- NES | c.3148del p.A1050Pfs*14 | Frame Shift Del (DEL) | VAF 77/247 reads (31%) | catalogued as rs1314116307; called by mutect2, pindel, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 115/352 reads (33%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NF1 | c.4291C>T p.P1431S (on ENST00000358273 / NM_001042492.3; = p.P1410S on NM_000267.3) | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as rs930267534, COSV62208716; called by muse, mutect2, varscan2
- NFATC1 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53703339; called by muse, mutect2
- NFE2 | c.661del p.E221Rfs*13 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | catalogued as COSV100380730; called by mutect2, pindel, varscan2
- NFRKB | c.163C>A p.L55I (on ENST00000446488 / NM_001143835.2; = p.L68I on NM_006165.3) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV100451768; called by muse, mutect2, varscan2
- NHLRC2 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63749805; called by muse, mutect2, varscan2
- NIBAN1 | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100836180; called by muse, mutect2, varscan2
- NIPBL | c.7207C>T p.R2403C | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99238549; called by muse, mutect2, varscan2
- NLGN2 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1479955408, COSV100080762; called by muse, mutect2, varscan2
- NLGN4Y | c.1532A>T p.N511I | Missense Mutation (SNP) | VAF 408/581 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59297277; called by muse, mutect2, varscan2
- NLRP2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs527958520, COSV54753596, COSV99672595; called by muse, mutect2, varscan2
- NOL8 | c.1169del p.N390Mfs*45 | Frame Shift Del (DEL) | VAF 99/270 reads (37%) | catalogued as rs757782481; called by mutect2, varscan2
- NOX3 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 52/166 reads (31%) | catalogued as rs560159515, COSV50151451; called by muse, varscan2
- NPEPL1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 220/624 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100622316; called by muse, mutect2, varscan2
- NRAP | c.4822G>A p.G1608S (on ENST00000359988 / NM_001322945.2; = p.G1573S on NM_006175.4) | Missense Mutation (SNP) | VAF 197/525 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs758527572, COSV100667771; called by muse, mutect2, varscan2
- NRAS | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 109/345 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs753954415, COSV54752206; called by muse, mutect2, varscan2
- NRG4 | c.291T>G p.D97E | Missense Mutation (SNP) | VAF 142/425 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV67530562; called by muse, varscan2
- NTN1 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99432156; called by muse, mutect2, varscan2
- NUP58 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1395392103, COSV101098534; called by muse, mutect2, varscan2
- NXF1 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53674173; called by muse, mutect2, varscan2
- NXF1 | c.1462-2A>G p.X488_splice | Splice Site (SNP) | VAF 40/111 reads (36%) | catalogued as COSV99585700; called by muse, mutect2, varscan2
- OAZ1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100457216; called by muse, mutect2, varscan2
- OBSCN | c.3925G>A p.A1309T | Missense Mutation (SNP) | VAF 148/488 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs768014393, COSV52736916, COSV52784717; called by muse, mutect2, varscan2
- OBSL1 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.508); catalogued as COSV99216129; called by muse, mutect2, varscan2
- OLFML2A | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs534548756, COSV99992342; called by muse, mutect2, varscan2
- OLFML3 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.314); catalogued as COSV100232930; called by muse, mutect2, varscan2
- ONECUT1 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 64/202 reads (32%) | catalogued as COSV100008996; called by muse, mutect2, varscan2
- ONECUT3 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs755669559, COSV66639836; called by muse, mutect2, varscan2
- OR1I1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV52917732; called by muse, varscan2
- OR1I1 | c.1062G>T p.M354I | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99264720; called by muse, varscan2
- OR1J2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 38/946 reads (4%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV100093100; called by muse, mutect2
- OR2G3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 242/690 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.29); catalogued as COSV60682453; called by muse, varscan2
- OR2Z1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 325/1008 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs782205923, COSV100136318; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 98/357 reads (27%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR5M10 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 231/681 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs758113779, COSV101595859; called by muse, mutect2, varscan2
- OR6C1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 222/825 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV101110439; called by muse, mutect2, varscan2
- OR6K2 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs150711789, COSV62743285, COSV62743462; called by muse, mutect2, varscan2
- OR6N1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100625049; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 156/528 reads (30%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OR8I2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 154/438 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs550211029, COSV56168689; called by muse, mutect2, varscan2
- ORC1 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs751699809, COSV65363247; called by muse, mutect2, varscan2
- OSBPL8 | c.354del p.E119Nfs*37 | Frame Shift Del (DEL) | VAF 91/323 reads (28%) | catalogued as rs1565866961, COSV53879345; called by mutect2, pindel, varscan2
- OTOP1 | c.517C>A p.H173N | Missense Mutation (SNP) | VAF 167/512 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762897240, COSV56394454; called by muse, mutect2, varscan2
- OTUD4 | c.2383G>A p.V795I (on ENST00000447906 / NM_001366057.1; = p.V730I on NM_001102653.1) | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.05); catalogued as COSV101485865; called by muse, mutect2, varscan2
- OVOL2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368800012; called by muse, mutect2, varscan2
- PACS2 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV100330582; called by muse, mutect2, varscan2
- PARD3B | c.2359A>G p.K787E (on ENST00000406610 / NM_001302769.2; = p.K725E on NM_152526.6) | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100592028; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 81/260 reads (31%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 116/296 reads (39%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56269665, COSV56274390; called by muse, mutect2, varscan2
- PBX3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 190/526 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs778017986, COSV100655185, COSV60732355; called by muse, mutect2, varscan2
- PBX4 | c.1063del p.Q355Nfs*25 | Frame Shift Del (DEL) | VAF 51/185 reads (28%) | catalogued as rs748202447; called by mutect2, pindel, varscan2
- PC | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV100852047; called by muse, mutect2, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 74/192 reads (39%) | catalogued as rs770881706; called by mutect2, varscan2
- PCDH15 | c.5584A>G p.M1862V | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100214516; called by muse, mutect2, varscan2
- PCDH18 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as rs1436017396, COSV100786999; called by muse, mutect2, varscan2
- PCDH19 | c.2657G>A p.R886Q (on ENST00000373034 / NM_001184880.2; = p.R839Q on NM_020766.3) | Missense Mutation (SNP) | VAF 195/295 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs757949591, COSV55267948, COSV99719357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA11 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.524); catalogued as COSV56475988; called by muse, mutect2, varscan2
- PCDHA12 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 153/417 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.292); catalogued as rs1030865953, COSV56496246; called by muse, mutect2, varscan2
- PCDHA7 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 208/659 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100971210; called by muse, mutect2, varscan2
- PCDHB12 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs1554286654, COSV53397087; called by muse, mutect2, varscan2
- PCDHB4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 171/493 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52025265; called by muse, mutect2, varscan2
- PCDHGA10 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.044); catalogued as rs1461729604, COSV53921947; called by muse, mutect2, varscan2
- PCDHGA2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV53976362; called by muse, mutect2, varscan2
- PCDHGB4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 412/1632 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1374592449, COSV99529668; called by muse, mutect2
- PCGF1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 159/421 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV99283160; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 174/540 reads (32%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PCOLCE | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs200657795, COSV99774877; called by muse, mutect2, varscan2
- PDCD10 | c.475-1G>T p.X159_splice | Splice Site (SNP) | VAF 18/474 reads (4%) | catalogued as CS050011, COSV101208496; called by muse, mutect2
- PDE2A | c.753A>T p.Q251H | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57809395; called by muse, mutect2
- PDS5B | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 155/440 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); catalogued as COSV100220413; called by muse, mutect2, varscan2
- PDZD2 | c.7854_7856del p.E2618del | In Frame Del (DEL) | VAF 40/120 reads (33%) | catalogued as rs751480688; called by pindel, varscan2
- PDZRN4 | c.1406C>T p.A469V (on ENST00000402685 / NM_001164595.2; = p.A211V on NM_013377.4) | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54206506; called by muse, mutect2, varscan2
- PEAR1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761777980, COSV99440531; called by muse, mutect2, varscan2
- PEBP4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 132/357 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as rs766153957, COSV56468503; called by muse, mutect2, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2, varscan2
- PHC1 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 188/1066 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101418499; called by muse, varscan2
- PHF12 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99255414; called by muse, mutect2, varscan2
- PHRF1 | c.1042C>G p.P348A | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52757934; called by muse, mutect2, varscan2
- PIAS3 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV100992624; called by muse, mutect2, varscan2
- PIGN | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201242848, COSV62950181; called by muse, mutect2, varscan2
- PIK3CG | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.053); catalogued as rs759136884, COSV63248027; called by muse, mutect2, varscan2
- PIK3R2 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs776438063, COSV99717155; called by muse, mutect2, varscan2
- PITPNM1 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653488; called by muse, mutect2, varscan2
- PKDREJ | c.5736G>T p.W1912C | Missense Mutation (SNP) | VAF 143/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775311485, COSV99478377; called by muse, mutect2, varscan2
- PKHD1 | c.197A>T p.N66I | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV100580916; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 100/369 reads (27%) | catalogued as rs769716668, COSV65737892; called by pindel, varscan2
- PLB1 | c.1454G>A p.R485K | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100214741; called by muse, mutect2, varscan2
- PLCXD1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs201625999, COSV67542080; called by muse, mutect2, varscan2
- PLEKHA4 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs370059930; called by muse, mutect2, varscan2
- PLEKHM1 | c.2397G>T p.E799D | Missense Mutation (SNP) | VAF 200/619 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.135); catalogued as COSV69599139, COSV69599437; called by muse, mutect2, varscan2
- PLEKHS1 | c.70T>C p.S24P (on ENST00000369310 / NM_182601.1; = p.S30P on NM_024889.5) | Missense Mutation (SNP) | VAF 140/418 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100732675; called by muse, mutect2, varscan2
- PLIN4 | c.1121del p.G374Afs*35 (on ENST00000301286; = p.G389Afs*35 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 160/377 reads (42%) | catalogued as rs766386520, COSV56686945; called by mutect2, pindel, varscan2
- PLXNA1 | c.4336A>G p.T1446A | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as COSV52524174; called by muse, mutect2, varscan2
- PLXNB1 | c.6020C>T p.A2007V | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755289308, COSV56492390; called by muse, mutect2, varscan2
- PLXND1 | c.5513A>G p.Y1838C | Missense Mutation (SNP) | VAF 171/482 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100138948; called by muse, mutect2, varscan2
- PNMA1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1472481770, COSV54094929; called by muse, mutect2, varscan2
- PNMT | c.203-1G>A p.X68_splice | Splice Site (SNP) | VAF 79/229 reads (34%) | catalogued as COSV99510461; called by muse, mutect2, varscan2
- PNPT1 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1303812368, COSV99569543; called by muse, mutect2, varscan2
- POF1B | c.609C>A p.H203Q | Missense Mutation (SNP) | VAF 225/295 reads (76%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as COSV99425939; called by muse, mutect2, varscan2
- POLR2B | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV100107771; called by muse, mutect2, varscan2
- POLR2E | c.289_291del p.E97del | In Frame Del (DEL) | VAF 68/236 reads (29%) | catalogued as rs767944502; called by pindel, varscan2
- POLR3H | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV53443735; called by muse, mutect2, varscan2
- PPFIA4 | c.1817C>T p.T606M (on ENST00000447715; = p.T607M on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs199626022, COSV55316238; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 112/331 reads (34%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1K | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.108); catalogued as rs537053098, COSV55796456; called by muse, mutect2, varscan2
- PPM1M | c.443G>A p.R148H (on ENST00000296487; = p.R309H on NM_144641.4) | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as rs554185326, COSV56599800; called by muse, mutect2, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 50/162 reads (31%) | catalogued as rs766639242; called by mutect2, varscan2
- PPP5C | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50139467; called by muse, mutect2, varscan2
- PRAG1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 141/374 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs367551818, COSV100421791; called by muse, mutect2, varscan2
- PRAMEF2 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1063787, COSV53576618; called by muse, mutect2
- PRAMEF7 | c.1278G>T p.W426C | Missense Mutation (SNP) | VAF 316/1915 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100435178; called by mutect2, varscan2
- PRELP | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs571164341, COSV100557737; called by muse, mutect2, varscan2
- PREP | c.971A>C p.K324T (on ENST00000369110; = p.K390T on NM_002726.5) | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV100963689; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 82/214 reads (38%) | catalogued as rs764112302; called by mutect2, varscan2
- PRIM1 | c.663del p.K221Nfs*24 | Frame Shift Del (DEL) | VAF 64/204 reads (31%) | catalogued as rs1194932333; called by mutect2, varscan2
- PRM2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs200756329, COSV54112988, COSV54113189; called by muse, mutect2, varscan2
- PRR23B | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.231); catalogued as COSV100271887; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 76/144 reads (53%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRSS53 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs776866243, COSV99761992; called by muse, mutect2, varscan2
- PSAPL1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs768726316, COSV100040291; called by muse, mutect2, varscan2
- PSMD12 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100635255; called by muse, mutect2, varscan2
- PTCH1 | c.2089C>A p.L697I | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV59481160; called by muse, mutect2, varscan2
- PTGDS | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99811667; called by muse, mutect2, varscan2
- PTK2 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 87/256 reads (34%) | catalogued as rs1247173286, COSV61788072; called by muse, mutect2, varscan2
- PTK2B | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs141042486; called by muse, mutect2, varscan2
- PTPN14 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.798); catalogued as rs200947677; called by muse, varscan2
- PTPN6 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59683437; called by muse, varscan2
- PTPN7 | c.266G>A p.R89H (on ENST00000495688; = p.R128H on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/397 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs766874694, COSV58313402; called by muse, mutect2, varscan2
- PTPRU | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs757579431, COSV60530658; called by muse, mutect2, varscan2
- PXDN | c.2570G>A p.C857Y | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99412131; called by muse, mutect2, varscan2
- QRICH1 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 276/747 reads (37%) | catalogued as COSV100676625; called by muse, mutect2, varscan2
- RAB13 | c.55dup p.V19Gfs*26 | Frame Shift Ins (INS) | VAF 93/317 reads (29%) | catalogued as rs1205539782; called by mutect2, pindel, varscan2
- RAB24 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs777474622, COSV100293435; called by muse, mutect2, varscan2
- RAB4B | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs746085545, COSV54570996; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 73/278 reads (26%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RAE1 | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100982336; called by muse, mutect2, varscan2
- RALB | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1282975021, COSV55603833; called by muse, mutect2, varscan2
- RAMP1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 150/428 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs757584759, COSV54538462; called by muse, mutect2, varscan2
- RANBP6 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52388434; called by muse, mutect2, varscan2
- RASAL3 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as COSV99652637; called by muse, mutect2, varscan2
- RASSF7 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 46/153 reads (30%) | catalogued as COSV100272351; called by muse, mutect2, varscan2
- RBBP6 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100154168; called by muse, mutect2, varscan2
- RBM12B | c.1519C>A p.H507N | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101234464; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 58/202 reads (29%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMX2 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 124/176 reads (70%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100564711; called by muse, mutect2, varscan2
- RCE1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 157/451 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100546948; called by muse, mutect2, varscan2
- RFX5 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142678277; called by muse, mutect2, varscan2
- RFXANK | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs749859039, COSV100284425; called by muse, mutect2, varscan2
- RGS9 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 134/416 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99287091; called by muse, varscan2
- RHBDF1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 177/531 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs573506725, COSV99244184; called by muse, mutect2, varscan2
- RIPK4 | c.1324G>A p.E442K (on ENST00000352483; = p.E394K on NM_020639.3) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs772576388, COSV100204599; called by muse, mutect2, varscan2
- RNF113B | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1287434043, COSV99940240; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 115/304 reads (38%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 149/396 reads (38%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- ROBO3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750349831, COSV67299213, COSV67301332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1 | c.4743del p.K1581Nfs*7 | Frame Shift Del (DEL) | VAF 84/202 reads (42%) | catalogued as COSV99607526; called by mutect2, varscan2
- RPGRIP1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs754461580, COSV52849598; called by muse, mutect2, varscan2
- RSPRY1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV101070904; called by muse, varscan2
- RSU1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 221/697 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV100590151; called by muse, mutect2, varscan2
- RYR2 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 239/679 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.824); catalogued as COSV100767544; called by muse, mutect2, varscan2
- SACS | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs34482854; called by muse, mutect2, varscan2
- SAFB2 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs1051172357, COSV53040506; called by muse, mutect2, varscan2
- SALL4 | c.3031G>A p.A1011T | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs370661697; called by muse, mutect2, varscan2
- SASH1 | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs547938889, COSV100820874; called by muse, mutect2, varscan2
- SBF2 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV99812928; called by muse, mutect2, varscan2
- SBF2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as COSV99812930; called by muse, mutect2, varscan2
- SCAF8 | c.2870T>C p.V957A | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1477378663, COSV100913882; called by muse, mutect2, varscan2
- SCARB2 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99357772; called by muse, mutect2, varscan2
- SCD | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100948841; called by muse, mutect2, varscan2
- SCMH1 | c.1850G>A p.R617H (on ENST00000326197 / NM_001031694.2; = p.R548H on NM_012236.4) | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143623408; called by muse, mutect2, varscan2
- SCMH1 | c.1342C>T p.R448C (on ENST00000326197 / NM_001031694.2; = p.R401C on NM_012236.4) | Missense Mutation (SNP) | VAF 183/549 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs146314489; called by muse, mutect2, varscan2
- SCN4A | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 155/460 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.937); catalogued as rs775418104, COSV101438304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16A | c.5435G>A p.R1812H | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51531977; called by muse, mutect2, varscan2
- SEMA3C | c.1651C>T p.R551* | Nonsense Mutation (SNP) | VAF 175/453 reads (39%) | catalogued as rs138526129, COSV99542289; called by muse, mutect2, varscan2
- SESN2 | c.722del p.P241Qfs*6 | Frame Shift Del (DEL) | VAF 64/213 reads (30%) | catalogued as rs770146088, COSV53426876; called by mutect2, pindel, varscan2
- SGSM1 | c.2281G>A p.G761S (on ENST00000400359 / NM_001039948.4; = p.G700S on NM_133454.3) | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs778812786, COSV100771847; called by muse, mutect2, varscan2
- SGSM3 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1412569100, COSV99960141; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 87/322 reads (27%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHMT1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs887752397, COSV57399441; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 85/309 reads (28%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SHROOM1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1024103394, COSV100167026, COSV60581796; called by muse, mutect2, varscan2
- SIGLEC5 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs764295708, COSV55781034; called by muse, mutect2, varscan2
- SIRT1 | c.1192T>C p.C398R | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99281564; called by muse, varscan2
- SIRT2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199856206, COSV50874874; called by muse, mutect2, varscan2
- SLC12A7 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 228/588 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755311022, COSV99369252; called by muse, mutect2, varscan2
- SLC14A2 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as rs556141911, COSV54907294, COSV54914502; called by muse, mutect2, varscan2
- SLC17A1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 98/325 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99765550; called by muse, mutect2, varscan2
- SLC1A1 | c.1415A>C p.Q472P | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99261140; called by muse, mutect2, varscan2
- SLC25A2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 129/369 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.532); catalogued as COSV99508145; called by muse, varscan2
- SLC27A2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51062527; called by muse, varscan2
- SLC2A1 | c.1412del p.G471Efs*37 | Frame Shift Del (DEL) | VAF 66/257 reads (26%) | catalogued as CD1413229; called by mutect2, pindel, varscan2
- SLC2A7 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773308377, COSV68901454; called by muse, mutect2, varscan2
- SLC38A10 | c.1469C>A p.P490H | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55846593; called by muse, mutect2, varscan2
- SLC44A5 | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 156/411 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100900963; called by muse, mutect2, varscan2
- SLC45A2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99672250; called by muse, mutect2, varscan2
- SLC6A15 | c.1900C>A p.P634T | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99880105; called by muse, mutect2, varscan2
- SLC7A11 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs763081007, COSV99762887; called by muse, mutect2, varscan2
- SLITRK3 | c.2591A>C p.E864A | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as COSV99578419; called by muse, mutect2, varscan2
- SLU7 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 170/507 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99775425; called by muse, mutect2, varscan2
- SMCHD1 | c.3015del p.D1006Tfs*39 | Frame Shift Del (DEL) | VAF 49/153 reads (32%) | catalogued as rs1568252824; called by mutect2, pindel, varscan2
- SMG1 | c.5481C>A p.F1827L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV67175111; called by muse, mutect2, varscan2
- SMIM21 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 196/644 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs968651103, COSV66895164; called by muse, mutect2, varscan2
- SMOC1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs769420307, COSV100734268; called by muse, mutect2, varscan2
- SNAP91 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV52126497; called by muse, mutect2, varscan2
- SNAPC4 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs140560641; called by muse, mutect2, varscan2
- SNTG1 | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52453712; called by muse, mutect2, varscan2
- SOGA3 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64105368; called by muse, mutect2
- SON | c.5051C>A p.P1684H | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as rs200562903, COSV99276688; called by muse, mutect2, varscan2
- SOX15 | c.498del p.S167Afs*64 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs1214200459; called by mutect2, varscan2
- SPAG11A | c.281del p.F94Sfs*43 (on ENST00000642566; = p.F94Sfs*63 on NM_001081552.3) | Frame Shift Del (DEL) | VAF 90/230 reads (39%) | catalogued as rs754013498, COSV58500193; called by mutect2, varscan2
- SPATA17 | c.1068del p.A357Lfs*13 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | catalogued as COSV65120767; called by mutect2, pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 57/197 reads (29%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPEN | c.6313del p.A2105Lfs*33 | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | catalogued as COSV65367511; called by mutect2, pindel, varscan2
- SPICE1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 205/583 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs376071843; called by muse, mutect2, varscan2
- SPOCK2 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.999); catalogued as rs369530712; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 130/361 reads (36%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPTA1 | c.4985C>T p.A1662V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1334578489, COSV100934149; called by muse, mutect2, varscan2
- SPTB | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs753867736, COSV67633724; called by muse, mutect2, varscan2
- SPTBN1 | c.6158A>C p.E2053A | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61690151; called by muse, mutect2, varscan2
- SRP14 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 201/616 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs200831083, COSV51116053; called by muse, varscan2
- SRRT | c.646del p.A216Pfs*6 | Frame Shift Del (DEL) | VAF 76/234 reads (32%) | catalogued as COSV61451248; called by mutect2, pindel, varscan2
- SRSF6 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 47/144 reads (33%) | catalogued as COSV54827962; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 394/1111 reads (35%) | PolyPhen probably damaging (0.979); catalogued as COSV100602327; called by muse, varscan2
- STAC2 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100336261, COSV61065819; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs752994755; called by mutect2, varscan2
- STOX2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs376960061, COSV57853685; called by muse, mutect2, varscan2
- SULT1C3 | c.41del p.K14Sfs*10 | Frame Shift Del (DEL) | VAF 108/320 reads (34%) | catalogued as rs770034585; called by mutect2, pindel, varscan2
- SULT6B1 | c.257dup p.Y87Vfs*2 (on ENST00000535679 / NM_001367551.1; = p.Y49Vfs*2 on NM_001032377.2) | Frame Shift Ins (INS) | VAF 40/162 reads (25%) | catalogued as rs747003550; called by mutect2, varscan2
- SUOX | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99906909; called by muse, mutect2, varscan2
- SUPV3L1 | c.1599+1G>C p.X533_splice | Splice Site (SNP) | VAF 89/256 reads (35%) | catalogued as COSV100669475; called by muse, mutect2, varscan2
- SURF4 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs878915690, COSV100914291; called by muse, mutect2, varscan2
- SVIL | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs376203305, COSV63442509; called by muse, mutect2, varscan2
- SYCP2 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 26/642 reads (4%) | catalogued as COSV100697907, COSV100697939; called by muse, mutect2
- SYN2 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs778458980, COSV101382975; called by muse, mutect2, varscan2
- SYNE1 | c.1941dup p.R648Sfs*22 (on ENST00000367255 / NM_182961.4; = p.R655Sfs*22 on NM_033071.3) | Frame Shift Ins (INS) | VAF 178/495 reads (36%) | catalogued as rs775516009; called by mutect2, varscan2
- SYNE4 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770457710, COSV53325075; called by muse, mutect2, varscan2
- TANC1 | c.3719T>C p.V1240A | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV55092958; called by muse, mutect2, varscan2
- TAOK2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 183/495 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54233552; called by muse, mutect2, varscan2
- TBC1D14 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 84/212 reads (40%) | catalogued as rs762979993, COSV100806026; called by muse, mutect2, varscan2
- TBC1D24 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs746963974, COSV53545402; called by muse, mutect2, varscan2
- TBXAS1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs373695119; called by muse, mutect2, varscan2
- TCERG1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99694337; called by muse, mutect2, varscan2
- TCP11 | c.88del p.Q30Rfs*19 (on ENST00000512012; = p.Q30Rfs*14 on NM_001261817.2) | Frame Shift Del (DEL) | VAF 70/231 reads (30%) | catalogued as rs751330115; called by mutect2, pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 73/201 reads (36%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR1 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768869253, COSV101130232; called by muse, mutect2, varscan2
- TEKT3 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 259/761 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100106726; called by muse, mutect2, varscan2
- TENM3 | c.3702C>G p.N1234K | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as COSV101304828; called by muse, mutect2, varscan2
- TET1 | c.4514G>A p.R1505H | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1288019869, COSV65388022; called by muse, mutect2, varscan2
- TET3 | c.4112A>G p.K1371R | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as rs1453548048, COSV101327569; called by muse, mutect2, varscan2
- TEX15 | c.3064G>T p.G1022* (on ENST00000256246; = p.G1405* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 195/607 reads (32%) | catalogued as COSV99820652; called by muse, mutect2, varscan2
- TGM5 | c.1784G>A p.R595H (on ENST00000220420 / NM_201631.4; = p.R513H on NM_004245.4) | Missense Mutation (SNP) | VAF 199/537 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as rs145147059, COSV55011261; called by muse, mutect2, varscan2
- THOP1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs762025666, COSV100310363; called by muse, mutect2, varscan2
- THSD7A | c.4949C>T p.A1650V | Missense Mutation (SNP) | VAF 501/1503 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101349152; called by muse, mutect2, varscan2
- TICAM1 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.306); catalogued as COSV50234014; called by muse, mutect2, varscan2
- TICRR | c.1367T>A p.I456K | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99175995; called by muse, mutect2, varscan2
- TIGD4 | c.533dup p.N178Kfs*4 | Frame Shift Ins (INS) | VAF 45/193 reads (23%) | catalogued as rs762008334; called by mutect2, pindel, varscan2
- TIGD6 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 157/464 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57061323, COSV99697750; called by muse, mutect2, varscan2
- TJP2 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779161706, COSV99600476; called by muse, mutect2, varscan2
- TLE5 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV99682222; called by muse, mutect2, varscan2
- TLL1 | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 75/190 reads (39%) | catalogued as rs773518843, COSV99285952; called by muse, mutect2, varscan2
- TLL2 | c.1397del p.G466Efs*3 | Frame Shift Del (DEL) | VAF 169/555 reads (30%) | catalogued as rs1261395235, COSV100780097; called by mutect2, pindel, varscan2
- TLN2 | c.3377C>T p.T1126M | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs535939717, COSV100167904; called by muse, mutect2, varscan2
- TLR5 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV100643150; called by muse, mutect2, varscan2
- TMC6 | c.1461del p.Y488Tfs*67 | Frame Shift Del (DEL) | VAF 96/298 reads (32%) | catalogued as COSV59810261; called by mutect2, pindel, varscan2
- TMEFF2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99770875; called by muse, mutect2, varscan2
- TMPRSS6 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs371794539, COSV60977639; ClinVar: uncertain significance; called by muse, mutect2
- TNC | c.3344A>T p.E1115V | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as COSV100404864; called by muse, mutect2, varscan2
- TNFSF8 | c.510dup p.Q171Tfs*8 | Frame Shift Ins (INS) | VAF 162/575 reads (28%) | catalogued as rs1456025599; called by mutect2, pindel, varscan2
- TNKS2 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 132/387 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1219601686, COSV100860982; called by muse, mutect2, varscan2
- TNPO2 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100790277; called by muse, mutect2, varscan2
- TOGARAM1 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as COSV100752955; called by muse, mutect2, varscan2
- TOGARAM1 | c.3854C>A p.A1285D | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100817766; called by muse, mutect2, varscan2
- TOP2B | c.3773T>C p.L1258P (on ENST00000264331 / NM_001330700.2; = p.L1253P on NM_001068.3) | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.327); catalogued as COSV99979046; called by muse, mutect2, varscan2
- TPBG | c.1049del p.P350Hfs*14 | Frame Shift Del (DEL) | VAF 63/440 reads (14%) | catalogued as rs1562154908, COSV63882849; called by mutect2, pindel, varscan2
- TPO | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774989776, CM119080, COSV100219577; called by muse, mutect2, varscan2
- TRABD | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57713515; called by muse, mutect2, varscan2
- TRIM39 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375880274, COSV100935607; called by muse, mutect2, varscan2
- TSC1 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV100051028; called by muse, mutect2
- TSGA10 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 127/392 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs758866582, COSV61822597; called by muse, mutect2, varscan2
- TTC17 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749177932, COSV50022434; called by muse, mutect2, varscan2
- TTC23L | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 199/594 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.242); catalogued as rs752667177, COSV72205759; called by muse, mutect2, varscan2
- TTC25 | c.1145+1G>A p.X382_splice | Splice Site (SNP) | VAF 72/157 reads (46%) | catalogued as rs189239015, COSV66368317; called by muse, mutect2, varscan2
- TTF1 | c.668del p.K223Rfs*45 | Frame Shift Del (DEL) | VAF 118/345 reads (34%) | catalogued as rs765042099; called by mutect2, varscan2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 74/259 reads (29%) | catalogued as rs751135082; called by mutect2, pindel, varscan2
- TTN | c.21920A>G p.E7307G (on ENST00000591111; = p.E6380G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/283 reads (37%) | PolyPhen benign (0.001); catalogued as COSV100592510; called by muse, mutect2, varscan2
- TTN | c.3244C>T p.P1082S (on ENST00000591111; = p.P1036S on NM_003319.4) | Missense Mutation (SNP) | VAF 86/272 reads (32%) | PolyPhen probably damaging (0.998); catalogued as COSV100592513; called by muse, mutect2, varscan2
- UBE2G2 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.742); catalogued as rs782079899, COSV58368401; called by muse, mutect2, varscan2
- UBR5 | c.7713del p.F2571Lfs*4 | Frame Shift Del (DEL) | VAF 60/215 reads (28%) | catalogued as rs1471902646; called by mutect2, pindel, varscan2
556 further variants in this file (229 protein-altering or splice-affecting, 301 silent, 26 other) are not listed here.
